Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A2MF, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A2MF-06A (Metastatic).

[page 1 of 2]
PathNet History Upload External
Client

DOB/Age/Sex:

Location:

Requested by:

Requested on:

Specimen Rcvd:

Accession No.:

Copies to: N/A

ARCHIVAL HISTOPATHOLOGY REPORT

Accession Number:

Collected Date:

HISTORICAL REQUEST DETAILS

CLINICAL NOTES

Previous melanoma (R) leg in ' Now (R) groin nodal mets + new primary
melanoma (R) upper cheek.

SPECIMEN INFORMATION

(R) groin dissection + (R) chest WEPC.

MACROSCOPIC DESCRIPTION

Two specimens were received.

I. "Right groin node". A groin dissection including the skin measuring 140 x 70 x 40mm, which is present at the edge. On sectioning, there are multiple lymph nodes, some involved by tumour. The largest metastatic lymph node measures approximately 45mm in diameter.

- A. 2 lymph nodes.
- B. 2 lymph nodes.
- C. Largest lymph node with tumour.
- D. 3 lymph nodes.
- E. 2 lymph nodes.
- F. 1 lymph node.

II. "Lesion right neck". An unorientated skin ellipse 40 x 15 x 5mm with a possible central scar approximately 20mm in length. There is also an irregular pale area approximately 5mm in the centre, lying 2mm from the convex margin.

A&B. Section through the centre of scar and irregular lesion.

C. Both ends of the skin ellipse.

MICROSCOPIC REPORT

I. "Right groin node". The section from the largest lymph node show a sheet of malignant cells consistent with metastatic melanoma. No evidence of malignancy seen in the remaining nodes.

ICD-0-3
Melanoma, NOS 8720/3
Site: lymph node, inguinal
C 77.4
lw
8/24/11

Primary Tumour Site Discrepancy		☒

[page 2 of 2]
Requested by: N/A

MRN/Name:

Location:

Accession:

ARCHIVAL HISTOPATHOLOGY REPORT

Accession Number:

Collected Date:

II. "Lesion right neck". Dermal scar. No residual malignancy seen.

Electronic signature

Verified by

SUMMARY / KEY WORDS

Lymph node, inguinal malignant melanoma, metastatic.

Skin of face - scar.

Haematopathology resection

Source: NCI Genomic Data Commons file f5983775-e987-419e-b710-42f385226b81 (TCGA-EE-A2MF.36A98990-59E2-494D-9682-690277F04C79.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).